Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A3HY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A3HY-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN #:

I.D.

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

- A. Left pelvic lymph nodes, excision:
Sixteen lymph nodes, negative for metastatic disease.
Frozen section diagnosis confirmed.
- B. Right pelvic lymph nodes, excision:
One of twenty lymph nodes positive for metastatic carcinoma.
Lymph node containing tumor not present on frozen slides.

- C. Uterus with bilateral adnexa, hysterectomy with bilateral salpingo-oophorectomy:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma, non-keratinizing.
2. Histologic grade: Grade II.
3. Tumor site: Cervix.
4. Tumor size: 5.5 by 4.0 cm.
5. Stromal invasion/depth/horizontal extent: Tumor extends 1.5 cm into a 1.6 cm thick cervical wall.
6. Lymphovascular space invasion: Focally present.

Surgical Margin Status:

1. Vaginal cuff: Negative.
2. Deep margin: Negative.
4. Paracervical tissues: Negative.

Lymph Node Status:

1. Three paracervical lymph nodes present, negative for metastatic disease.
2. See parts A, B.
- Other:
1. Other significant findings: Bilateral adnexa without significant pathologic abnormality.
2. pTNM stage: pT1b2 N1.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Squamous cell cervix carcinoma.
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left pelvic - FS.
- B. Right pelvic - FS.
- C. Uterus, cervix, BSO.

SPECIMENDATA

GROSS DESCRIPTION:

The specimen is received in three containers labeled with the patient's name

A. Container A is additionally labeled #1 and contains a 6.5 x 6.0 x 3.0 cm. aggregate of yellow-tan fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.3 up to 7.0 cm. in greatest dimension. Five possible lymph nodes are submitted for frozen section with the residual entirely re-submitted for permanent section in cassette A1 labeled

All remaining possible lymph nodes are submitted in cassettes A2-8 designated as follows: A2 and 3--four whole possible lymph nodes in each

ICD-0-3

carcinoma, squamous cell, non-keratinizing, NOS 8072/3

Site: cervix, NOS C53.9

hw 12/2/11

[page 2 of 2]
cassette; A4 and 5—one whole possible bisected lymph node in each cassette; A6-8 one whole possible lymph node, serially sectioned.

B. Container B is additionally labeled right pelvic and contains a 6.5 x 6.5 x 2.5 cm. aggregate of yellow-tan fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified up to 5.0 cm. in greatest dimension. Sections from four possible lymph nodes are submitted for frozen section with residual entirely re-submitted for permanent section in cassette B1 labeled. All remaining possible lymphoid tissue is submitted in cassettes B2 through 10 labeled on designated as follows: B2—four whole possible lymph nodes; B3—five whole possible lymph nodes; B4—two whole possible bisected lymph nodes (one inked); B5 through 8—one whole possible bisected lymph node in each cassette; B9 and 10—one whole possible quadrisectioned lymph node.

C. Container C is additionally labeled uterus, cervix, BSO and contains a 22 gram radical hysterectomy specimen received with detached bilateral adnexa. The specimen is comprised of uterine corpus (6.5 cm. in length by 5.5 x 5.1 cm.), uterine cervix (4.5 cm. in length by 3.3 x 3.2 cm.), vaginal cuff (1.5 cm. in length), right paracervical soft tissue (3.5 x 3.0 x 1.8 cm.), and left paracervical soft tissue (4.5 x 4.0 x 2.5 cm.). The corpus is smooth and glistening. The ectocervical mucosa is pink-tan glistening and features a yellow-tan granular rim surrounding the 1.2 cm. patulous, patent os. Sections through the paracervical soft tissue reveal a yellow-tan vascular cut surface along with three firm fatty possible lymph nodes within the left paracervical tissues. These possible lymph nodes range from 0.5 to 0.7 cm. in greatest dimension. The specimen is bivalved to reveal a 5.5 x 4.0 cm. yellow-tan ulcerated, fungating mass that involves the endocervical canal and is contiguous with the aforementioned cervical os granularity. This mass extends to the level of the lower uterine segment and invades 1.5 cm. into a 1.6 cm. thick endocervix. The triangular endometrium is pink-tan and glistening with an average thickness of 0.2 cm. The surrounding myometrium is pink-tan fibrous and slightly trabeculated with an average thickness of 2.8 cm. No myometrial nodules or lesions are identified.

The first fimbriated fallopian tube is 3.0 cm. in length and ranges from 0.5 to 0.7 cm. in diameter. The attached yellow-tan lobulated ovary is 2.7 x 1.8 x 0.9 cm. The cut surface is yellow-tan and fibrous with a tan-orange corpus luteum and two uniloculated cysts, 0.3 and 0.4 cm. in greatest dimension. The cysts feature smooth inner linings and contain clear, watery fluid.

The second fimbriated fallopian tube is 3.5 cm. in length and ranges from 0.4 to 0.7 cm. in diameter. The attached yellow-tan lobulated ovary is 2.8 x 2.1 x 0.9 cm. The cut surface is yellow-tan and fibrous with multiple gray-white corpora albicantia.

Representative sections are submitted in cassettes C1-19 labeled as follows: 1—right paracervical soft tissue, perpendicular; 2—left paracervical soft tissue, perpendicular; 3—three whole possible left paracervical lymph nodes; 4—anterior vaginal cuff, en face; 5—posterior vaginal cuff, en face; 6 through 8—full thickness sections of anterior endocervix to include ectocervix in cassette 6; cassettes 9—bisected full thickness posterior endocervix (notched ends adjoined); 10 and 11—full thickness posterior endocervix to include additional ectocervical mucosa in cassettes C11, 12. 12 is anterior lower uterine segment; 13—posterior lower uterine segment; 14 and 15—full thickness anterior endomyometrium; 16 and 17—full thickness posterior endomyometrium; 18—first tube and ovary; 19—second tube and ovary.

Additionally, a yellow, green and blue cassette are submitted for Genomics research each labeled

INTRA-OPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS: No tumor identified (0/5) per Dr. J

B. FROZEN SECTION DIAGNOSIS: No tumor identified (0/4) per Dr. J

Source: NCI Genomic Data Commons file ea5595c2-103d-41b9-ae70-309e88b8b755 (TCGA-FU-A3HY.4048896F-495E-434F-8849-1DA13FD6C2A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).